Somatic mutation profile of tumor specimen MMRF_1808_1_BM_CD138pos (aliquot MMRF_1808_1_BM_CD138pos_T1_KBS5U_K11305) from MMRF case MMRF_1808, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,619 days).
Specimen MMRF_1808_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 586f48d7-7bef-4c78-8fbf-80210e0c2471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1808_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1808_1_PB_Whole_C2_KBS5U_K11306; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63dd4987-7874-4aed-aa39-d82a404eac26

The open-access MAF lists 88 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 27, Silent 12, Intron 8, Splice Region 3, 5'UTR 3, Frame Shift Ins 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP4 | c.1163dup p.A389Sfs*? | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | catalogued as rs1237192462; called by mutect2, pindel, varscan2
- ASXL2 | c.986A>T p.N329I | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710279; called by muse, mutect2
- BAAT | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV52289965, COSV99408683; called by muse, mutect2, varscan2
- CLC | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs1243347855; called by muse, mutect2, varscan2
- DNAH9 | c.5605G>A p.A1869T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs574060515, COSV52377842; called by muse, mutect2, varscan2
- EIF3H | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99411842; called by muse, mutect2
- IGHV2-70 | c.253A>C p.K85Q | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs755889609; called by muse, varscan2
- IGLV3-10 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs184893196; called by muse, mutect2, varscan2
- LIMS2 | c.238+8C>T | Splice Region (SNP) | VAF 55/123 reads (45%) | catalogued as rs370024589; called by muse, mutect2, varscan2
- LUC7L2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.019); catalogued as rs749245444; called by muse, mutect2, varscan2
- MROH2A | c.3602G>A p.R1201Q | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as rs1423907639; called by muse, mutect2, varscan2
- MYH8 | c.4987G>A p.A1663T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as rs1175404788; called by muse, mutect2, varscan2
- PAX7 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs746781983, COSV64751687; called by muse, mutect2, varscan2
- PSMB1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416252126, COSV51529853; called by muse, mutect2, varscan2
- SPTLC2 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1205341271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLL1 | c.2665G>A p.G889R | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376169735; called by muse, mutect2, varscan2
- TOGARAM2 | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as rs534450625, COSV65421418; called by muse, mutect2, varscan2
- ZNF793 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs759077203, COSV71325173; called by muse, mutect2, varscan2
- DPYSL3 | c.11_12insT p.R5Pfs*125 | Frame Shift Ins (INS) | VAF 26/56 reads (46%) | called by mutect2, pindel, varscan2
- ECD | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- EDIL3 | c.469A>C p.K157Q | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FGD5 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 156/486 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- FRY | c.7724G>A p.S2575N | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GSAP | c.2562A>T p.L854F | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGF1R | c.2349T>A p.D783E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHJ4 | c.24_31del p.T9Hfs*? | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | called by pindel, varscan2
- KIF4B | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- KITLG | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PCDHA11 | c.543T>G p.D181E | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.02); called by muse, mutect2
- PRRG4 | c.105G>A p.V35= | Splice Region (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2
- PXN | c.406A>G p.T136A | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNF111 | c.2298-8G>A | Splice Region (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- SPATA7 | c.1523A>C p.Q508P | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SRCAP | c.8762C>A p.P2921H | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TBX18 | c.1662C>A p.F554L | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TMEM39A | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZFYVE21 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CD7 | c.531T>C p.S177= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- DRP2 | c.744C>T p.S248= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- IGHJ4 | c.45A>T p.S15= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs141539541; called by muse, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 48/54 reads (89%) | catalogued as rs367953381; called by muse, varscan2
- IGHV2-70D | c.246A>C p.T82= | Silent (SNP) | VAF 32/47 reads (68%) | called by muse, varscan2
- ITPRIPL2 | c.819C>T p.R273= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- LIN7C | c.387T>C p.D129= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs375407727; called by muse, mutect2, varscan2
- LYVE1 | c.435C>T p.T145= | Silent (SNP) | VAF 49/196 reads (25%) | called by muse, mutect2, varscan2
- OR6C65 | c.429A>T p.V143= | Silent (SNP) | VAF 103/223 reads (46%) | called by muse, mutect2, varscan2
- SMC6 | c.1668G>C p.G556= | Silent (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- TAF7 | c.159T>C p.H53= | Silent (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- ZHX2 | c.879C>G p.S293= | Silent (SNP) | VAF 80/153 reads (52%) | called by muse, mutect2, varscan2
- ARHGEF7 | c.823-2608G>A | Intron (SNP) | VAF 53/107 reads (50%) | catalogued as rs976498178, COSV99521363; called by muse, mutect2, varscan2
- ATP5PB | c.*1097T>C | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.*1428G>T | 3'UTR (SNP) | VAF 20/38 reads (53%) | catalogued as rs1258941200; called by muse, mutect2, varscan2
- BHLHE41 | c.*1356T>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- C17orf80 | chr17:73232435 G>C | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- CAPN14 | c.*137A>G | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- CCER1 | c.-390G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as rs1243622387; called by mutect2, varscan2
- CCKBR | c.403+42C>T | Intron (SNP) | VAF 30/220 reads (14%) | catalogued as rs1249516602; called by muse, mutect2, varscan2
- CDH11 | c.*2041T>G | 3'UTR (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- CUX1 | c.*1934T>A | 3'UTR (SNP) | VAF 21/55 reads (38%) | catalogued as rs185400269; called by muse, mutect2, varscan2
- DNAH14 | c.1825+638A>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- DOCK4 | c.2473+48G>A | Intron (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- FAM217B | c.*2960G>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs1034926980; called by muse, varscan2
- FPGT-TNNI3K | c.383-2474A>G | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- FZD10 | c.*611C>T | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- H2AC4 | c.*4G>C | 3'UTR (SNP) | VAF 67/152 reads (44%) | called by muse, mutect2, varscan2
- IL20RB | c.*106G>C | 3'UTR (SNP) | VAF 108/360 reads (30%) | called by muse, mutect2, varscan2
- IZUMO4 | c.*178G>A | 3'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- MGME1 | c.*68T>C | 3'UTR (SNP) | VAF 62/265 reads (23%) | called by muse, mutect2, varscan2
- MMP16 | c.*4084T>C | 3'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- MTTP | c.*762G>A | 3'UTR (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*4082C>T | 3'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- NKPD1 | c.*27G>A | 3'UTR (SNP) | VAF 34/158 reads (22%) | catalogued as rs1413567168; called by muse, mutect2, varscan2
- NOX4 | c.*1010C>T | 3'UTR (SNP) | VAF 59/446 reads (13%) | catalogued as rs1180145037; called by muse, mutect2, varscan2
- NTRK3 | c.1586-38426C>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs1292323825, COSV100446224; called by muse, mutect2, varscan2
- OR6C65 | c.*11A>C | 3'UTR (SNP) | VAF 96/212 reads (45%) | called by muse, varscan2
- PKDCC | c.*347A>G | 3'UTR (SNP) | VAF 31/81 reads (38%) | catalogued as rs944676081; called by muse, mutect2, varscan2
- POU4F3 | c.-28C>T | 5'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- PRRG3 | c.*346G>A | 3'UTR (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- PRTG | c.*6010C>G | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- PTPA | c.*739C>T | 3'UTR (SNP) | VAF 89/145 reads (61%) | called by muse, mutect2, varscan2
- RTN4 | c.3013+14889T>C | Intron (SNP) | VAF 20/517 reads (4%) | called by muse, mutect2
- S1PR3 | c.*853C>T | 3'UTR (SNP) | VAF 21/61 reads (34%) | catalogued as rs1009004581; called by muse, mutect2, varscan2
- SLC26A2 | c.*5570A>C | 3'UTR (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- SYNE1 | c.26153+1346T>C | Intron (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- TOP1 | c.-233A>G | 5'UTR (SNP) | VAF 19/58 reads (33%) | catalogued as rs975819527; called by muse, mutect2, varscan2
- ZBTB21 | c.*2471G>C | 3'UTR (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- ZBTB21 | c.*2470G>C | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- ZBTB44 | c.*1568T>C | 3'UTR (SNP) | VAF 56/220 reads (25%) | called by muse, mutect2, varscan2
